Somatic mutation profile of tumor specimen C3N-00310-01 (aliquot CPT0008980009) from CPTAC case C3N-00310, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 84.9 years (31,016 days).
Specimen C3N-00310-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80b62af8-6cde-453b-b5ff-cd45fdced5f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00310-31 (Blood Derived Normal), aliquot CPT0009030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b72d4395-f10d-44d6-81fc-443e8f35274d

The open-access MAF lists 130 somatic variants for this specimen: 84 protein-altering or splice-affecting, 29 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 29, Intron 12, Frame Shift Del 10, Splice Site 4, Nonsense Mutation 3, RNA 2, 3'UTR 2, Frame Shift Ins 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.340+2T>A p.X114_splice | Splice Site (SNP) | VAF 57/442 reads (13%) | hotspot (GDC flag); catalogued as CD983001, COSV56547957, COSV56551654, COSV56551713, COSV56563827; called by muse, mutect2, varscan2
- CACNG3 | c.819G>C p.K273N | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV50085386; called by muse, mutect2, varscan2
- CCDC65 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.87); catalogued as rs376799979; called by muse, mutect2, varscan2
- CENPJ | c.4000A>G p.M1334V | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs774140825; called by muse, mutect2, varscan2
- CLDN16 | c.615del p.A206Pfs*26 | Frame Shift Del (DEL) | VAF 30/244 reads (12%) | catalogued as CM060926; called by mutect2, pindel, varscan2
- COLEC12 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs765394463, COSV68374660; called by muse, mutect2, varscan2
- CSMD3 | c.3395C>A p.P1132Q (on ENST00000297405 / NM_001363185.1; = p.P1028Q on NM_052900.3) | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765683126; called by muse, mutect2, varscan2
- DGKZ | c.2057C>G p.S686C (on ENST00000454345 / NM_001105540.2; = p.S498C on NM_003646.4) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV58988293; called by muse, mutect2
- DOCK5 | c.4037C>T p.A1346V | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52395508, COSV52404091; called by muse, mutect2, varscan2
- DOK4 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1422790855, COSV99538313; called by muse, mutect2
- FKBP9 | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.863); catalogued as rs796764966; called by muse, mutect2, varscan2
- HCN4 | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs373284500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGSF1 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.536); catalogued as rs750533250, COSV63839200; called by muse, mutect2, varscan2
- LRBA | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs945099173; ClinVar: uncertain significance; called by muse, mutect2
- MAPKBP1 | c.3070C>T p.L1024F (on ENST00000456763 / NM_001128608.2; = p.L1018F on NM_014994.3) | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1463119166; called by muse, mutect2
- MATN4 | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 15/99 reads (15%) | PolyPhen probably damaging (1); catalogued as COSV59213028; called by muse, mutect2, varscan2
- MTUS1 | c.2271G>T p.R757S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.382); catalogued as rs777233433; called by muse, mutect2, varscan2
- MUC2 | c.2942C>T p.A981V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs766848359; called by muse, mutect2
- MYH14 | c.3513G>C p.E1171D | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs748451285; called by muse, mutect2, varscan2
- PIAS4 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs368054611, COSV53681082; called by muse, mutect2, varscan2
- PRKCQ | c.1607C>T p.T536M | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756942026, COSV54119832; called by muse, mutect2, varscan2
- SMARCA4 | c.3304T>C p.F1102L | Missense Mutation (SNP) | VAF 67/611 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60790620; called by muse, mutect2, varscan2
- STPG3 | c.108C>G p.T36= | Splice Region (SNP) | VAF 8/90 reads (9%) | catalogued as COSV100547010; called by muse, mutect2
- TLK1 | c.587T>G p.F196C | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.784); catalogued as rs1021006550; called by muse, mutect2, varscan2
- ZFAND4 | c.1823A>T p.E608V | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs762806906; called by muse, mutect2, varscan2
- AHCTF1 | c.2345C>T p.T782I (on ENST00000366508; = p.T756I on NM_015446.5) | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ARHGEF17 | c.5546T>A p.L1849Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- ARHGEF3 | c.607G>C p.G203R | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ATP1B1 | c.376dup p.C126Lfs*7 | Frame Shift Ins (INS) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- BBS4 | c.435C>A p.Y145* | Nonsense Mutation (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- CACNA1C | c.3474G>T p.M1158I | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); called by muse, mutect2
- CBFA2T3 | c.1364C>A p.P455H | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- CDK17 | c.397_400del p.H133Dfs*8 | Frame Shift Del (DEL) | VAF 9/97 reads (9%) | called by mutect2, pindel, varscan2
- CENPJ | c.2692+1G>C p.X898_splice | Splice Site (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- CIB3 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.214); called by muse, mutect2
- CLCN5 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- CNPY3 | c.728G>A p.S243N | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CPAMD8 | c.5272G>A p.G1758S (on ENST00000651564; = p.G1711S on NM_015692.5) | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT tolerated, low confidence (0.76); PolyPhen possibly damaging (0.563); called by muse, mutect2
- DGLUCY | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DGUOK | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 56/464 reads (12%) | called by muse, mutect2, varscan2
- DIAPH1 | c.2473+1G>A p.X825_splice | Splice Site (SNP) | VAF 42/397 reads (11%) | called by muse, mutect2, varscan2
- DPYSL5 | c.29T>A p.I10N | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- EIPR1 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM200A | c.1558T>C p.F520L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCGBP | c.4149C>G p.Y1383* | Nonsense Mutation (SNP) | VAF 76/738 reads (10%) | called by muse, varscan2
- FCHO2 | c.2003C>G p.S668C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- FTSJ3 | c.1819C>A p.L607I | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2
- GABRA4 | c.1331C>G p.T444S | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GALNT7 | c.1817A>C p.K606T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- GARNL3 | c.2709A>C p.K903N | Missense Mutation (SNP) | VAF 40/350 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GIMAP6 | c.798del p.E266Dfs*122 | Frame Shift Del (DEL) | VAF 42/321 reads (13%) | called by mutect2, pindel, varscan2
- HEATR5B | c.2833G>A p.D945N | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HOXA2 | c.14T>A p.F5Y | Missense Mutation (SNP) | VAF 33/388 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- HSFX4 | c.397A>C p.N133H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- KDM5C | c.2885del p.P962Lfs*16 | Frame Shift Del (DEL) | VAF 43/179 reads (24%) | called by mutect2, pindel, varscan2
- LTB4R | c.968_971del p.Q323Pfs*25 | Frame Shift Del (DEL) | VAF 11/94 reads (12%) | called by mutect2, pindel, varscan2
- MRPL44 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- NBN | c.221A>C p.Y74S | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5AN1 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PBRM1 | c.2225_2226del p.E742Vfs*16 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel, varscan2
- PCDH8 | c.2467A>C p.T823P | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PHTF1 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PIGN | c.878C>G p.P293R | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PITPNM2 | c.2946del p.S983Qfs*14 | Frame Shift Del (DEL) | VAF 47/306 reads (15%) | called by mutect2, pindel, varscan2
- PLA2G4D | c.488G>A p.C163Y | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PLXND1 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PXMP4 | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RGL1 | c.2221A>G p.K741E (on ENST00000360851 / NM_001297672.2; = p.K776E on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2
- RNF128 | c.1150A>C p.T384P (on ENST00000255499 / NM_194463.2; = p.T358P on NM_024539.3) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.124); called by muse, varscan2
- RNF20 | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- SEC31A | c.938C>A p.P313H | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- SETD2 | c.6211_6212del p.N2071* | Frame Shift Del (DEL) | VAF 25/214 reads (12%) | called by mutect2, pindel, varscan2
- SLCO2A1 | c.1026T>G p.I342M | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA2L | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPDL1 | c.82T>A p.L28I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPTBN1 | c.567-1G>T p.X189_splice | Splice Site (SNP) | VAF 16/124 reads (13%) | called by mutect2, varscan2
- TBX19 | c.1157C>A p.P386Q | Missense Mutation (SNP) | VAF 75/510 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TG | c.5728del p.T1910Qfs*32 | Frame Shift Del (DEL) | VAF 49/379 reads (13%) | called by mutect2, pindel, varscan2
- TSNAXIP1 | c.426del p.K142Nfs*12 | Frame Shift Del (DEL) | VAF 27/228 reads (12%) | called by mutect2, pindel, varscan2
- TTN | c.48170G>A p.G16057D (on ENST00000591111; = p.G8633D on NM_003319.4) | Missense Mutation (SNP) | VAF 53/470 reads (11%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBE2V2 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- USP53 | c.1949T>A p.I650K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- ZNF207 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- ZNF792 | c.1610G>A p.S537N | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AATK | c.138C>T p.I46= | Silent (SNP) | VAF 49/312 reads (16%) | catalogued as rs746392822; called by muse, mutect2, varscan2
- ADGRG1 | c.276C>G p.L92= | Silent (SNP) | VAF 86/710 reads (12%) | called by muse, mutect2, varscan2
- ATP10A | c.1746C>T p.V582= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs369407036; called by muse, mutect2
- ATP8B2 | c.627A>G p.V209= (on ENST00000672630; = p.V176= on NM_001005855.2) | Silent (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- AVEN | c.544T>C p.L182= | Silent (SNP) | VAF 27/192 reads (14%) | called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.909T>A p.I303= | Silent (SNP) | VAF 22/167 reads (13%) | called by muse, mutect2, varscan2
- DCUN1D2 | c.369A>G p.L123= | Silent (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2
- FAM204A | c.12G>T p.G4= | Silent (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- FCN3 | c.336T>C p.P112= | Silent (SNP) | VAF 18/219 reads (8%) | called by muse, mutect2
- IGFBP7 | c.135G>A p.P45= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs11555292; called by muse, mutect2
- IL4R | c.534C>T p.T178= | Silent (SNP) | VAF 30/171 reads (18%) | called by muse, mutect2, varscan2
- KDR | c.1563G>A p.A521= | Silent (SNP) | VAF 45/448 reads (10%) | catalogued as rs200769864, COSV55771803; called by muse, mutect2, varscan2
- KRT7 | c.132C>T p.A44= | Silent (SNP) | VAF 28/309 reads (9%) | called by muse, mutect2
- MAP3K11 | c.1296G>C p.R432= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- NDUFS2 | c.456T>C p.S152= | Silent (SNP) | VAF 64/548 reads (12%) | called by muse, mutect2, varscan2
- NFASC | c.2112C>T p.A704= (on ENST00000339876 / NM_001378329.1; = p.A700= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/440 reads (9%) | called by muse, mutect2
- NUP98 | c.3141G>A p.G1047= (on ENST00000359171 / NM_001365126.1; = p.G1030= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- OPRD1 | c.510C>T p.I170= | Silent (SNP) | VAF 29/222 reads (13%) | called by muse, mutect2, varscan2
- PILRA | c.282G>A p.V94= | Silent (SNP) | VAF 56/600 reads (9%) | catalogued as COSV104388762; called by muse, mutect2
- PKHD1 | c.7953A>C p.L2651= | Silent (SNP) | VAF 24/143 reads (17%) | called by muse, mutect2, varscan2
- POMT1 | c.714C>T p.V238= | Silent (SNP) | VAF 66/563 reads (12%) | called by muse, mutect2, varscan2
- RUSC1 | c.999G>T p.P333= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as rs751785225; called by muse, mutect2, varscan2
- SLC26A2 | c.765A>C p.G255= | Silent (SNP) | VAF 25/184 reads (14%) | called by muse, mutect2, varscan2
- SPNS1 | c.726A>C p.P242= | Silent (SNP) | VAF 48/391 reads (12%) | called by muse, mutect2, varscan2
- SRSF10 | c.192T>G p.A64= | Silent (SNP) | VAF 18/143 reads (13%) | catalogued as COSV100086941; called by muse, mutect2, varscan2
- UMOD | c.417G>C p.A139= | Silent (SNP) | VAF 52/382 reads (14%) | called by muse, mutect2, varscan2
- ZBED6 | c.558G>A p.R186= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as rs1401224748; called by muse, mutect2, varscan2
- ZC3H12C | c.1062T>C p.D354= | Silent (SNP) | VAF 41/274 reads (15%) | called by muse, mutect2, varscan2
- ZNF469 | c.9156C>T p.G3052= (on ENST00000437464; = p.G3080= on NM_001367624.2) | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as rs1204859520; called by muse, mutect2
- ABCA13 | c.12070+74T>G | Intron (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- AC004890.2 | n.2388G>C | RNA (SNP) | VAF 10/96 reads (10%) | called by muse, varscan2
- AC244517.10 | c.36-9071C>T | Intron (SNP) | VAF 98/943 reads (10%) | catalogued as COSV101595564; called by muse, mutect2, varscan2
- BRINP2 | c.461-66T>C | Intron (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- C7orf50 | c.130-18160G>A | Intron (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- DCAF12 | c.79-296C>A | Intron (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2
- HLX | c.957+20A>C | Intron (SNP) | VAF 13/136 reads (10%) | called by muse, mutect2
- IGSF22 | c.*63del | 3'UTR (DEL) | VAF 34/370 reads (9%) | called by mutect2, pindel
- KAZALD1 | chr10:101067948 C>T | 3'Flank (SNP) | VAF 32/225 reads (14%) | called by muse, mutect2, varscan2
- LIMCH1 | c.2243-786C>T | Intron (SNP) | VAF 22/258 reads (9%) | catalogued as rs757602137, COSV58285020; called by muse, mutect2
- MKRN3 | c.*21C>T | 3'UTR (SNP) | VAF 13/98 reads (13%) | catalogued as rs764997431; called by muse, mutect2, varscan2
- MUC19 | n.5319G>C | RNA (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- NEB | c.11601+6152G>A | Intron (SNP) | VAF 42/716 reads (6%) | catalogued as rs772352938; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- NT5C2 | c.687+9T>C | Intron (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2
- PIK3CD | c.-138+2446G>A | Intron (SNP) | VAF 60/650 reads (9%) | called by muse, mutect2
- ROBO3 | c.2846+22C>T | Intron (SNP) | VAF 30/224 reads (13%) | called by muse, mutect2, varscan2
- WDR38 | c.308-10G>C | Intron (SNP) | VAF 40/375 reads (11%) | called by muse, mutect2, varscan2
